Somatic mutation profile of tumor specimen ALCH-B01Q-TTP1-A (aliquot ALCH-B01Q-TTP1-A-3-0-D-A709-36) from ALCHEMIST case ALCH-B01Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 70.4 years (25,701 days).
Specimen ALCH-B01Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 195b8ecb-3494-4353-96eb-9e0d83eacc89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01Q-NB1-A (Blood Derived Normal), aliquot ALCH-B01Q-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2530e1e-90f8-4edc-a781-61ad294ccb99

The open-access MAF lists 2,454 somatic variants for this specimen: 1,656 protein-altering or splice-affecting, 486 silent, 312 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,398, Silent 486, Intron 151, Nonsense Mutation 102, Frame Shift Del 57, RNA 55, Splice Site 51, 3'UTR 40, 5'UTR 27, Splice Region 25, 5'Flank 22, 3'Flank 17.

Variants (750 of 2,454; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 307/988 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs137854533, COSV55670877, COSV55673870; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ2 | c.1160del p.P387Rfs*2 (on ENST00000359125 / NM_172107.4; = p.P377Rfs*2 on NM_004518.6) | Frame Shift Del (DEL) | VAF 71/267 reads (27%) | catalogued as rs796052657, COSV60542103; ClinVar: pathogenic; called by mutect2, varscan2
- PTCH1 | c.1348-2A>G p.X450_splice | Splice Site (SNP) | VAF 34/267 reads (13%) | catalogued as rs1064793978, CS127979; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 43/108 reads (40%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.878A>G p.K293R (on ENST00000502732 / NM_007314.4; = p.K278R on NM_005158.5) | Missense Mutation (SNP) | VAF 64/290 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as rs551340084; called by muse, varscan2
- AC004922.1 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 50/462 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.062); catalogued as rs137914882; called by muse, mutect2, varscan2
- ACSBG1 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99357353; called by muse, mutect2
- ACTN2 | c.2219C>A p.T740N | Missense Mutation (SNP) | VAF 89/385 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63975026; called by muse, mutect2, varscan2
- ADAM23 | c.2237C>A p.S746* | Nonsense Mutation (SNP) | VAF 48/129 reads (37%) | catalogued as COSV52220908; called by muse, mutect2, varscan2
- ADAMTS8 | c.2329C>A p.Q777K | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as rs768016902; called by muse, mutect2, varscan2
- ADAMTS8 | c.1692C>G p.Y564* | Nonsense Mutation (SNP) | VAF 52/195 reads (27%) | catalogued as COSV99961169; called by muse, mutect2, varscan2
- ADCY2 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs145761834; called by muse, mutect2, varscan2
- ADCY5 | c.2616C>A p.S872R | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100567124; called by muse, mutect2, varscan2
- ADCY8 | c.3050A>G p.D1017G | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.752); catalogued as rs539555378; called by muse, mutect2, varscan2
- AKAP9 | c.2791G>T p.G931C | Missense Mutation (SNP) | VAF 191/495 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV62349169; called by muse, mutect2, varscan2
- ALCAM | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 55/289 reads (19%) | catalogued as rs951490893, COSV100065705; called by muse, mutect2, varscan2
- ALOX5 | c.1528G>A p.V510M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.62); catalogued as rs1426065454, COSV65552814; called by muse, mutect2, varscan2
- ALX3 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as rs1408091351; called by muse, mutect2, varscan2
- AMTN | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 80/345 reads (23%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); catalogued as rs374431307; called by muse, mutect2, varscan2
- ANAPC13 | c.171G>T p.W57C | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61566396; called by muse, mutect2, varscan2
- ANK2 | c.7567G>T p.E2523* | Nonsense Mutation (SNP) | VAF 28/142 reads (20%) | catalogued as COSV52149446, COSV52164372; called by muse, mutect2, varscan2
- ANK2 | c.10364G>T p.G3455V | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs533201814; called by muse, varscan2
- ANK2 | c.10376C>A p.P3459H | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100002316, COSV100003936; called by muse, varscan2
- ANKRD42 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs770312357, COSV99473737; called by muse, mutect2, varscan2
- AP002512.3 | c.1046C>T p.T349M | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs558210028, COSV54405409; called by muse, mutect2, varscan2
- AP3B1 | c.1862C>T p.T621I | Missense Mutation (SNP) | VAF 52/540 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV54889687; called by muse, mutect2
- ARAP1 | c.1328G>T p.R443L (on ENST00000393609 / NM_001040118.2; = p.R198L on NM_015242.4) | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV61993832; called by muse, mutect2, varscan2
- AREL1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1268969629; called by muse, mutect2, varscan2
- ARHGAP22 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752933087, COSV50977793; called by muse, mutect2, varscan2
- ARHGAP36 | c.931T>C p.Y311H | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV52269077; called by muse, mutect2, varscan2
- ARHGEF3 | c.1228+6G>C | Splice Region (SNP) | VAF 44/129 reads (34%) | catalogued as rs553026463; called by muse, mutect2, varscan2
- ARID1A | c.4555C>A p.Q1519K | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV61374802, COSV61386977; called by muse, mutect2, varscan2
- ARL16 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 128/247 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs774636076, COSV100230290, COSV61270642; called by muse, mutect2, varscan2
- ASPM | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 89/547 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs780791970, COSV54136935, COSV54140446; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP10B | c.4015C>G p.P1339A | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV59149700; called by muse, mutect2, varscan2
- ATP10B | c.1521G>T p.R507S | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV58782176; called by muse, mutect2, varscan2
- ATP1A4 | c.2011G>A p.V671M | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1433717783; called by muse, mutect2, varscan2
- ATP2B3 | c.160G>T p.G54W | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54860039; called by muse, mutect2, varscan2
- ATP4A | c.2281C>A p.L761M | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99382322; called by muse, mutect2, varscan2
- ATP4A | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 117/337 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); catalogued as COSV52866824; called by muse, mutect2, varscan2
- AUP1 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV57815939; called by muse, mutect2, varscan2
- BBS10 | c.1747A>G p.M583V | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV67913098; called by muse, mutect2, varscan2
- BCL2L12 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs200984195; called by muse, mutect2, varscan2
- BNC1 | c.937A>G p.K313E | Missense Mutation (SNP) | VAF 57/229 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV61756499, COSV61757336; called by muse, mutect2, varscan2
- BSX | c.397C>A p.R133S | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58005533; called by muse, varscan2
- BTBD16 | c.555del p.A186Pfs*16 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as rs1192746728; called by mutect2, pindel, varscan2
- C2CD3 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as rs755686768, COSV100486097, COSV58091084; called by muse, mutect2, varscan2
- C5orf51 | c.533G>T p.R178L | Missense Mutation (SNP) | VAF 52/513 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370411797, COSV101069011; called by muse, mutect2, varscan2
- CABIN1 | c.4166C>A p.T1389K | Missense Mutation (SNP) | VAF 63/375 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV104371081; called by muse, mutect2, varscan2
- CACNA1F | c.2713G>T p.G905C | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100544771; called by muse, mutect2, varscan2
- CALCB | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60834184, COSV60834476; called by muse, varscan2
- CAPN12 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100185501; called by muse, mutect2, varscan2
- CBARP | c.797C>A p.S266* (on ENST00000382477; = p.S246* on NM_152769.3) | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | catalogued as rs367906910; called by muse, mutect2, varscan2
- CBLN1 | c.348C>A p.F116L | Missense Mutation (SNP) | VAF 109/221 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292082742; called by muse, mutect2, varscan2
- CCDC172 | c.74G>T p.R25L | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV60939317; called by muse, mutect2, varscan2
- CCDC73 | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100067949; called by muse, mutect2, varscan2
- CCDC8 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 135/302 reads (45%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749133236; called by muse, mutect2, varscan2
- CCKBR | c.577A>C p.T193P | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV58103006; called by muse, mutect2, varscan2
- CCL25 | c.11G>T p.W4L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV53663838; called by muse, mutect2, varscan2
- CCNB1IP1 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 92/310 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.499); catalogued as rs766670075, COSV62303608; called by muse, mutect2, varscan2
- CD1A | c.605-1G>T p.X202_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99192583; called by muse, mutect2
- CD1B | c.220G>T p.G74C | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63804045; called by muse, mutect2, varscan2
- CD40 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 68/275 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1464002562; called by muse, mutect2, varscan2
- CDH10 | c.121G>T p.V41L | Missense Mutation (SNP) | VAF 394/742 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs752914373; called by muse, mutect2
- CDH12 | c.1531A>G p.S511G | Missense Mutation (SNP) | VAF 44/476 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1221114402; called by muse, mutect2
- CDH17 | c.2402T>A p.I801K | Missense Mutation (SNP) | VAF 117/256 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs1368713490; called by muse, mutect2, varscan2
- CDS2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV100986198; called by muse, mutect2, varscan2
- CECR2 | c.3049G>A p.E1017K (on ENST00000342247 / NM_001290047.2; = p.E833K on NM_001290046.1) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.165); catalogued as rs768076456; called by muse, mutect2, varscan2
- CEL | c.1720G>A p.V574M (on ENST00000673714; = p.V571M on NM_001807.6) | Missense Mutation (SNP) | VAF 112/256 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1341866900; called by muse, varscan2
- CELA3B | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs767734311; called by muse, mutect2, varscan2
- CEP72 | c.753G>T p.Q251H | Missense Mutation (SNP) | VAF 411/693 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV53793047; called by muse, mutect2, varscan2
- CEP97 | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59124901; called by muse, mutect2, varscan2
- CFAP157 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 48/196 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as rs541406158; called by muse, mutect2, varscan2
- CFAP47 | c.7777G>T p.D2593Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV66220132; called by muse, varscan2
- CFAP74 | c.1140T>A p.H380Q | Missense Mutation (SNP) | VAF 77/296 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs779394985; called by muse, mutect2, varscan2
- CFHR2 | c.811T>C p.*271Qext*7 | Nonstop Mutation (SNP) | VAF 42/199 reads (21%) | catalogued as rs754554648; called by muse, varscan2
- CHD8 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 85/502 reads (17%) | catalogued as rs1348950904; called by muse, mutect2, varscan2
- CHD9 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV68296866; called by muse, mutect2, varscan2
- CHIT1 | c.418del p.E140Sfs*11 | Frame Shift Del (DEL) | VAF 67/408 reads (16%) | catalogued as rs750736893; called by mutect2, pindel, varscan2
- CLEC2A | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 105/372 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV60273910; called by muse, mutect2, varscan2
- CLEC3A | c.292C>A p.H98N (on ENST00000651443; = p.H89N on NM_005752.6) | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV55222374; called by muse, mutect2, varscan2
- CLEC4D | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100222924, COSV55227887; called by muse, mutect2, varscan2
- CMKLR1 | c.957G>T p.M319I (on ENST00000312143 / NM_001142344.2; = p.M317I on NM_004072.3) | Missense Mutation (SNP) | VAF 136/300 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV56438182; called by muse, mutect2, varscan2
- CNGB3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 197/424 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as rs778936684; called by muse, mutect2, varscan2
- COL11A1 | c.4474G>T p.G1492C | Missense Mutation (SNP) | VAF 38/486 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV62175684; called by muse, mutect2
- COL18A1 | c.2695C>T p.R899W (on ENST00000359759 / NM_130444.3; = p.R664W on NM_030582.4) | Missense Mutation (SNP) | VAF 101/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs755768318; called by muse, mutect2, varscan2
- COL19A1 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.601); catalogued as rs1391825541; called by muse, varscan2
- COL20A1 | c.2215G>T p.V739L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100489871; called by muse, mutect2, varscan2
- COL3A1 | c.1816-1G>T p.X606_splice | Splice Site (SNP) | VAF 222/503 reads (44%) | catalogued as COSV100482273, COSV58588114; called by muse, mutect2, varscan2
- COL3A1 | c.3208G>T p.A1070S | Missense Mutation (SNP) | VAF 226/551 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.274); catalogued as rs376738516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A5 | c.926C>G p.P309R | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.977); catalogued as rs778279260; called by muse, mutect2, varscan2
- COL4A6 | c.3814C>G p.R1272G | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.9); catalogued as rs757302174, COSV57879691; called by muse, mutect2, varscan2
- COL6A6 | c.5714C>A p.S1905* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | catalogued as COSV62018612; called by muse, mutect2, varscan2
- COQ2 | c.988A>T p.S330C | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV61021686; called by muse, mutect2
- CPEB4 | c.37A>T p.N13Y | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV54173894; called by muse, mutect2
- CRACD | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.197); catalogued as rs1458464761, COSV51715755, COSV99949755; called by muse, mutect2, varscan2
- CRMP1 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV61479200; called by muse, mutect2, varscan2
- CRNKL1 | c.322G>C p.V108L | Missense Mutation (SNP) | VAF 89/372 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV99842909; called by muse, mutect2, varscan2
- CT47B1 | c.107G>A p.G36D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.943); catalogued as rs1199544594; called by muse, varscan2
- CTNNA3 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57721046; called by muse, mutect2, varscan2
- CUX2 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55624897; called by muse, mutect2, varscan2
- CYP4F8 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100358269; called by muse, mutect2, varscan2
- DAB2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 62/614 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs201380557, COSV57912080, COSV57914097; called by muse, mutect2
- DAXX | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56467210; called by muse, mutect2, varscan2
- DCAF12 | c.796-2A>T p.X266_splice | Splice Site (SNP) | VAF 32/308 reads (10%) | catalogued as COSV63513401; called by muse, mutect2, varscan2
- DCC | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 309/838 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59081290; called by muse, mutect2, varscan2
- DCDC2 | c.840del p.E281Kfs*3 | Frame Shift Del (DEL) | VAF 22/238 reads (9%) | catalogued as rs766360855; called by mutect2, pindel
- DDRGK1 | c.296-1G>T p.X99_splice | Splice Site (SNP) | VAF 51/161 reads (32%) | catalogued as COSV100621409; called by muse, mutect2, varscan2
- DDX50 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV65292533; called by muse, mutect2
- DENND2C | c.1122G>C p.L374F | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67921390; called by muse, mutect2, varscan2
- DENND2C | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV67920394; called by muse, mutect2, varscan2
- DISP3 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53822232; called by muse, mutect2, varscan2
- DKK2 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 110/457 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs757495574, COSV53396763, COSV53403317; called by muse, mutect2, varscan2
- DLGAP3 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV52397172; called by muse, mutect2, varscan2
- DMRT3 | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51905948; called by muse, mutect2, varscan2
- DNAH1 | c.8393G>T p.R2798L | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV70235968; called by muse, mutect2, varscan2
- DNAH9 | c.6493C>T p.H2165Y | Missense Mutation (SNP) | VAF 20/369 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as rs1460056179; called by muse, mutect2
- DNAI3 | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs150647021; called by muse, mutect2, varscan2
- DRC7 | c.1120A>G p.M374V | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.297); catalogued as rs765306232, COSV61057370; called by muse, mutect2, varscan2
- DUOX2 | c.3632G>C p.R1211P | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM152115, COSV66531770; called by muse, mutect2, varscan2
- DYNC1I1 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 151/378 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61473906; called by muse, mutect2, varscan2
- DYNC2H1 | c.12073A>G p.I4025V | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1417472286, COSV62106036; called by muse, mutect2, varscan2
- EBF1 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV100566342; called by muse, mutect2, varscan2
- ECI1 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs772827843; called by muse, mutect2, varscan2
- EFR3A | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 80/256 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1364816753, COSV54461560; called by muse, mutect2, varscan2
- EGR4 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV71531919; called by muse, mutect2, varscan2
- ELMO1 | c.1490G>C p.S497T | Missense Mutation (SNP) | VAF 96/366 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs956711929, COSV60319976; called by muse, mutect2, varscan2
- ELSPBP1 | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.228); catalogued as COSV60413212, COSV60414974; called by muse, varscan2
- EP400 | c.4403G>T p.G1468V | Missense Mutation (SNP) | VAF 104/149 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs377608091; called by muse, mutect2, varscan2
- EPB41L5 | c.1962+1G>T p.X654_splice | Splice Site (SNP) | VAF 48/135 reads (36%) | catalogued as COSV55352538; called by muse, mutect2, varscan2
- EPG5 | c.4224A>G p.I1408M | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs953377599; called by muse, mutect2, varscan2
- EPHA1 | c.922G>C p.A308P | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV99314239; called by muse, mutect2, varscan2
- EPHA5 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 101/472 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV56668040; called by muse, mutect2, varscan2
- EPHB2 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV65864068; called by mutect2, varscan2
- EPS15L1 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs1329198075; called by muse, mutect2, varscan2
- EYA2 | c.546C>A p.Y182* | Nonsense Mutation (SNP) | VAF 70/270 reads (26%) | catalogued as COSV57941322; called by muse, varscan2
- F11 | c.703G>A p.G235S | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.023); catalogued as rs762316798, CM0910289, COSV99251570; called by muse, mutect2, varscan2
- F5 | c.2022G>T p.K674N | Missense Mutation (SNP) | VAF 53/283 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541355758; called by muse, mutect2, varscan2
- FAM47C | c.109C>A p.R37S | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.583); catalogued as COSV63723797; called by muse, mutect2, varscan2
- FAM53A | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1427415768; called by muse, mutect2, varscan2
- FAT1 | c.1679A>G p.N560S | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as rs965372725; called by muse, mutect2, varscan2
- FBN2 | c.1232-2A>G p.X411_splice | Splice Site (SNP) | VAF 88/369 reads (24%) | catalogued as rs1354013406; called by muse, mutect2, varscan2
- FBXL7 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 110/187 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61641904, COSV61644880; called by muse, mutect2, varscan2
- FCGR2A | c.632G>T p.G211V (on ENST00000271450 / NM_001136219.3; = p.G210V on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54838270; called by muse, mutect2, varscan2
- FCRL1 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 76/464 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63826341; called by muse, mutect2, varscan2
- FCRL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 32/268 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV63844250; called by muse, mutect2, varscan2
- FCRLA | c.800C>A p.T267N (on ENST00000367959; = p.T244N on NM_032738.4) | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1457871660; called by muse, mutect2, varscan2
- FCRLA | c.830C>A p.P277H (on ENST00000367959; = p.P254H on NM_032738.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99376349; called by muse, mutect2, varscan2
- FLG | c.6590A>G p.E2197G | Missense Mutation (SNP) | VAF 168/732 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs757771714; called by muse, mutect2, varscan2
- FLG | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 95/659 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV100911995; called by muse, mutect2, varscan2
- FLG2 | c.6086G>T p.G2029V | Missense Mutation (SNP) | VAF 128/502 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1486568010; called by muse, varscan2
- FLNC | c.4783G>T p.D1595Y | Missense Mutation (SNP) | VAF 53/471 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780133859, COSV57950864, COSV57963095; called by muse, mutect2, varscan2
- FLNC | c.5596G>A p.G1866R | Missense Mutation (SNP) | VAF 185/479 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100368332; called by muse, mutect2, varscan2
- FLOT2 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV101204770; called by muse, mutect2, varscan2
- FLT4 | c.3688T>A p.Y1230N | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV56120017; called by muse, mutect2, varscan2
- FLT4 | c.1249G>T p.V417L | Missense Mutation (SNP) | VAF 89/316 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.1); catalogued as COSV56123820; called by muse, mutect2, varscan2
- FLT4 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56117818, COSV56124518; called by muse, mutect2, varscan2
- FOLH1 | c.793G>T p.G265* | Nonsense Mutation (SNP) | VAF 43/312 reads (14%) | catalogued as COSV99923488; called by muse, mutect2, varscan2
- FOXRED1 | c.703G>C p.G235R | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55007915; called by muse, mutect2, varscan2
- FOXRED1 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757274475; called by muse, mutect2, varscan2
- FRMPD4 | c.2356C>A p.L786M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66220650; called by muse, mutect2, varscan2
- FRRS1L | c.244C>G p.P82A | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs761224976, COSV101643944; called by muse, mutect2, varscan2
- FSIP1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as COSV63224664; called by muse, mutect2, varscan2
- FSIP2 | c.5324C>T p.S1775F | Missense Mutation (SNP) | VAF 23/295 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV58090330; called by muse, mutect2
- FXYD2 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 76/280 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.559); catalogued as rs1382229203; called by muse, mutect2, varscan2
- GABRA5 | c.614G>T p.W205L | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59479151, COSV59482663; called by muse, mutect2, varscan2
- GABRB3 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 90/379 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54677218; called by muse, mutect2, varscan2
- GABRG1 | c.1288G>C p.G430R | Missense Mutation (SNP) | VAF 134/648 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV54949890; called by muse, mutect2, varscan2
- GALNT12 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 201/575 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1304031845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA1 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64964016; called by muse, mutect2, varscan2
- GBP1 | c.1009C>A p.Q337K | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs766833210; called by muse, mutect2, varscan2
- GCSAML | c.255T>A p.N85K | Missense Mutation (SNP) | VAF 70/413 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV100825906; called by muse, mutect2, varscan2
- GDAP1 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 255/472 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV55184756; called by muse, mutect2, varscan2
- GFRA3 | c.633C>A p.H211Q | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV51231085; called by muse, mutect2, varscan2
- GFRA4 | c.754G>T p.G252W (on ENST00000319242 / NM_145762.3; = p.G222W on NM_022139.4) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99293987; called by muse, mutect2, varscan2
- GLDN | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.878); catalogued as rs569083008; called by muse, varscan2
- GLIPR1L2 | c.480+2T>A p.X160_splice | Splice Site (SNP) | VAF 52/125 reads (42%) | catalogued as rs1416108852; called by muse, mutect2, varscan2
- GNAS | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV58326333; called by muse, mutect2, varscan2
- GP9 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 147/461 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56624740; called by muse, mutect2, varscan2
- GPA33 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100901194; called by muse, mutect2, varscan2
- GPR148 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.27); catalogued as COSV59307950; called by muse, mutect2, varscan2
- GRID2IP | c.1826C>A p.P609H | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1348278579; called by muse, mutect2, varscan2
- GUCA2B | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.273); catalogued as rs1264854206; called by muse, mutect2, varscan2
- GUCY2F | c.2009G>T p.R670M | Missense Mutation (SNP) | VAF 82/146 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV54302384; called by muse, mutect2, varscan2
- H1-4 | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99175368; called by muse, mutect2
- HBB | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 120/455 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs33976006, CM810022, CM950616, COSV58941722; ClinVar: other; called by muse, mutect2, varscan2
- HCN3 | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.001); catalogued as rs569376899, COSV100712772; called by muse, mutect2, varscan2
- HDC | c.1381C>A p.L461M | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.804); catalogued as COSV51068557; called by muse, mutect2, varscan2
- HELT | c.602C>G p.P201R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV58820205; called by muse, mutect2, varscan2
- HERC2 | c.8741G>T p.R2914L | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as rs566182373, COSV99871222; called by muse, mutect2, varscan2
- HIVEP2 | c.3347G>T p.R1116L | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.987); catalogued as rs199589962; called by muse, mutect2, varscan2
- HNRNPCL2 | c.728del p.G243Vfs*27 | Frame Shift Del (DEL) | VAF 59/281 reads (21%) | catalogued as rs1013057453; called by mutect2, pindel, varscan2
- HOXA4 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 154/295 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs778824475, COSV57826955; called by muse, mutect2, varscan2
- HSD17B14 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 38/272 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV54361098; called by muse, varscan2
- IDUA | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM073130; called by muse, mutect2, varscan2
- IFT122 | c.2612G>T p.W871L (on ENST00000348417 / NM_052989.3; = p.W812L on NM_018262.4) | Missense Mutation (SNP) | VAF 121/497 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as rs764716919; called by muse, mutect2, varscan2
- IGF2 | c.325+1G>T p.X109_splice (on ENST00000434045 / NM_001127598.3; = p.X53_splice on NM_000612.6) | Splice Site (SNP) | VAF 12/60 reads (20%) | catalogued as COSV56100192; called by muse, mutect2
- IGSF22 | c.1852A>T p.T618S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1259144207; called by muse, mutect2, varscan2
- IL17A | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs780929803, COSV60684362; called by muse, mutect2, varscan2
- IL32 | c.638G>T p.G213V (on ENST00000396890 / NM_001308078.4; = p.G167V on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV99145590; called by muse, mutect2, varscan2
- INSC | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.012); catalogued as COSV65410016; called by muse, mutect2, varscan2
- INSIG1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 72/165 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60920775; called by muse, mutect2, varscan2
- INSRR | c.3625G>A p.G1209R | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748727844; called by muse, mutect2, varscan2
- ISL2 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.196); catalogued as rs1055341567; called by muse, mutect2, varscan2
- ITPRID1 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 8/73 reads (11%) | catalogued as rs777536724; called by mutect2, varscan2
- ITPRIPL2 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs774651415; called by muse, mutect2, varscan2
- JAKMIP1 | c.2296C>A p.R766S | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV68955286; called by mutect2, varscan2
- JPH2 | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 59/167 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.163); catalogued as rs1475379949, COSV65905469; called by muse, mutect2, varscan2
- KANK3 | c.569T>C p.M190T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs1392993456; called by muse, mutect2, varscan2
- KANK4 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100587572, COSV62988416; called by muse, mutect2, varscan2
- KCNA3 | c.803C>G p.S268W | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV63901708; called by muse, mutect2, varscan2
- KCNA4 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 72/261 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV100068606; called by muse, varscan2
- KCNB1 | c.2009G>T p.R670L | Missense Mutation (SNP) | VAF 118/396 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as rs753575587, COSV100870420, COSV100870610; called by muse, mutect2, varscan2
- KCNH3 | c.1883A>T p.E628V | Missense Mutation (SNP) | VAF 41/59 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57793304; called by muse, mutect2, varscan2
- KCNJ5 | c.463C>G p.R155G | Missense Mutation (SNP) | VAF 65/567 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57971669; called by muse, mutect2, varscan2
- KCNK3 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 95/167 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1281102056; called by muse, mutect2, varscan2
- KCNQ2 | c.1543G>A p.E515K (on ENST00000359125 / NM_172107.4; = p.E487K on NM_004518.6) | Missense Mutation (SNP) | VAF 119/331 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60546101; called by muse, mutect2, varscan2
- KCNT1 | c.1616G>T p.G539V (on ENST00000488444; = p.G558V on NM_020822.3) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as rs760272242; called by muse, mutect2, varscan2
- KCTD17 | c.853G>T p.A285S (on ENST00000403888 / NM_001282684.1; = p.A261S on NM_024681.3) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.038); catalogued as rs1436205077; called by muse, mutect2, varscan2
- KDM3B | c.3344G>A p.R1115Q | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455341790, COSV100070438; called by muse, mutect2, varscan2
- KIF21B | c.2343C>A p.N781K | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs959484745; called by muse, mutect2, varscan2
- KIF5A | c.1365G>T p.L455= | Splice Region (SNP) | VAF 92/209 reads (44%) | catalogued as rs1316537934, COSV54054864; called by muse, mutect2, varscan2
- KIZ | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982373968; called by muse, mutect2, varscan2
- KLHL4 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100910248; called by muse, mutect2, varscan2
- KLHL6 | c.1423G>T p.G475* | Nonsense Mutation (SNP) | VAF 92/554 reads (17%) | catalogued as COSV58069344; called by muse, mutect2, varscan2
- KLRB1 | c.266C>A p.P89Q | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs767621944, COSV99987194, COSV99987378; called by muse, mutect2, varscan2
- KMT5B | c.1655C>A p.S552Y | Missense Mutation (SNP) | VAF 126/405 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV58564431; called by muse, mutect2, varscan2
- KRBA1 | c.155-1G>A p.X52_splice | Splice Site (SNP) | VAF 19/122 reads (16%) | catalogued as rs777880445; called by muse, varscan2
- KRI1 | c.927G>T p.S309= | Splice Region (SNP) | VAF 20/57 reads (35%) | catalogued as rs772345684; called by muse, mutect2, varscan2
- KRT77 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1489800117, COSV59241682; called by muse, varscan2
- KRTAP2-2 | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs1256476644; called by muse, varscan2
- KRTAP4-11 | c.102C>A p.C34* | Nonsense Mutation (SNP) | VAF 90/221 reads (41%) | catalogued as COSV66948664; called by muse, varscan2
- KSR1 | c.1961G>T p.C654F (on ENST00000644974 / NM_001367810.1; = p.C539F on NM_014238.2) | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52041286; called by muse, mutect2, varscan2
- LCE1C | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 90/555 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV64219325; called by muse, mutect2, varscan2
- LILRB2 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 43/558 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs1163331995, COSV58745830; called by muse, mutect2
- LILRB5 | c.1375G>T p.G459W (on ENST00000449561 / NM_001081442.3; = p.G458W on NM_006840.5) | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100300194; called by muse, mutect2, varscan2
- LINGO1 | c.717C>A p.Y239* | Nonsense Mutation (SNP) | VAF 32/224 reads (14%) | catalogued as rs778170323, COSV62438962; called by muse, mutect2, varscan2
- LMTK3 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54318563; called by muse, mutect2, varscan2
- LMX1A | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs909983869, COSV54218563, COSV99672908; called by muse, mutect2, varscan2
- LOXHD1 | c.5224C>A p.R1742S (on ENST00000642948; = p.R631S on NM_001145472.3) | Missense Mutation (SNP) | VAF 135/278 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as rs561122654; called by muse, mutect2, varscan2
- LOXHD1 | c.3619+1G>T p.X1207_splice | Splice Site (SNP) | VAF 46/206 reads (22%) | catalogued as rs1001401581; called by muse, varscan2
- LPIN3 | c.1043G>T p.W348L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.829); catalogued as COSV100952865; called by muse, mutect2
- LRFN5 | c.928del p.A310Pfs*40 | Frame Shift Del (DEL) | VAF 46/290 reads (16%) | catalogued as COSV53271853; called by pindel, varscan2
- LRIT1 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV64513493; called by muse, mutect2, varscan2
- LRP2 | c.4892A>G p.H1631R | Missense Mutation (SNP) | VAF 210/455 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs1309942116; called by muse, mutect2, varscan2
- LTBP2 | c.1902C>G p.D634E | Missense Mutation (SNP) | VAF 252/685 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV56209731; called by muse, mutect2, varscan2
- M1AP | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs756749449; called by muse, mutect2, varscan2
- MAGEC1 | c.572A>T p.E191V | Missense Mutation (SNP) | VAF 106/336 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV53572683; called by muse, varscan2
- MAML2 | c.1660G>T p.G554C | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.818); catalogued as rs1253501876; called by muse, mutect2, varscan2
- MAN1A1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as rs1358225220, COSV63781321; called by muse, mutect2, varscan2
- MAP2K1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT tolerated (0.95); PolyPhen benign (0.006); catalogued as rs1567009717; called by muse, mutect2, varscan2
- MAP3K3 | c.1144G>T p.V382L | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV62281291; called by muse, mutect2, varscan2
- MAPK4 | c.110C>A p.A37D | Missense Mutation (SNP) | VAF 163/624 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68542178; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1029G>T p.E343D | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); catalogued as rs868673897; called by muse, mutect2, varscan2
- MAPRE2 | c.85A>T p.S29C | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV68975365; called by muse, mutect2, varscan2
- MBL2 | c.498G>T p.R166S | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV64758036; called by muse, mutect2
- MDGA2 | c.2621G>C p.R874P (on ENST00000399232 / NM_001113498.2; = p.R576P on NM_182830.4) | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV62084032; called by muse, varscan2
- MEGF10 | c.2569G>T p.G857W | Missense Mutation (SNP) | VAF 91/366 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57257500; called by muse, mutect2, varscan2
- MEX3B | c.1244G>C p.G415A | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as rs1207766242; called by muse, varscan2
- MFSD8 | c.1351G>T p.G451C | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553943557; called by muse, mutect2, varscan2
- MGA | c.7698G>T p.R2566S (on ENST00000219905 / NM_001164273.1; = p.R2357S on NM_001080541.2) | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV54951397, COSV99579143; called by muse, mutect2, varscan2
- MGAM2 | c.5725A>G p.I1909V | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT tolerated, low confidence (1); catalogued as rs1321705112; called by muse, mutect2, varscan2
- MIA | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV54571890, COSV54572307; called by muse, mutect2, varscan2
- MINAR1 | c.2221C>A p.R741S | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as rs766575910, COSV59583124; called by muse, mutect2, varscan2
- MKRN1 | c.716G>A p.C239Y | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99751495; called by muse, mutect2
- MNDA | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV63739889; called by muse, mutect2, varscan2
- MPPED1 | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV68837436; called by muse, mutect2, varscan2
- MROH7 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100274190, COSV59878454; called by muse, mutect2, varscan2
- MROH7 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs376972881; called by muse, mutect2, varscan2
- MTREX | c.240del p.R81Gfs*2 | Frame Shift Del (DEL) | VAF 16/138 reads (12%) | catalogued as rs771658803; called by mutect2, varscan2
- MTUS2 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 135/409 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.415); catalogued as rs1303647157, COSV70912425; called by muse, mutect2, varscan2
- MUC16 | c.37303C>A p.P12435T | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.222); catalogued as COSV101202300; called by muse, mutect2, varscan2
- MUC16 | c.27092C>T p.T9031M | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs779780074; called by muse, mutect2, varscan2
- MUC16 | c.23829C>A p.H7943Q | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV67447436; called by muse, mutect2, varscan2
- MUC16 | c.23131C>A p.P7711T | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.266); catalogued as rs578258727, COSV67455199; called by muse, mutect2, varscan2
- MUC16 | c.23037del p.F7680Lfs*2 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as COSV67495770; called by mutect2, pindel, varscan2
- MYH2 | c.3425G>T p.R1142L | Missense Mutation (SNP) | VAF 178/375 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55442072; called by muse, mutect2, varscan2
- MYH7 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 71/392 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV62516437; called by muse, varscan2
- MYO1F | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57799774; called by muse, mutect2, varscan2
- MYO9A | c.7252C>G p.Q2418E | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.039); catalogued as rs1372171290; called by muse, mutect2, varscan2
- MYOM2 | c.3059C>A p.S1020* | Nonsense Mutation (SNP) | VAF 44/125 reads (35%) | catalogued as COSV50705365, COSV50753905; called by muse, mutect2, varscan2
- NAGLU | c.2042C>A p.A681E | Missense Mutation (SNP) | VAF 72/546 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV56794710; called by muse, mutect2, varscan2
- NANOS2 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1205550114, COSV58025183, COSV58025531; called by muse, mutect2, varscan2
- NAT8L | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as COSV59051023; called by muse, mutect2, varscan2
- NAV3 | c.4939G>T p.A1647S | Missense Mutation (SNP) | VAF 90/229 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs1476578129, COSV57102325; called by muse, mutect2, varscan2
- NBPF1 | c.2527C>G p.P843A | Missense Mutation (SNP) | VAF 100/470 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.279); catalogued as COSV55323490; called by muse, mutect2, varscan2
- NCKAP5 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166948606; called by muse, mutect2, varscan2
- NEB | c.13393G>A p.G4465S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.999); catalogued as rs1239862833; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NETO1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1039286504; called by muse, varscan2
- NF1 | c.3749G>T p.R1250L | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs199474765, CM000800, CM145566, COSV62196892, COSV62208991; ClinVar: uncertain significance; called by muse, mutect2
- NFASC | c.2539C>T p.H847Y (on ENST00000339876 / NM_001378329.1; = p.H950Y on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV58371970; called by muse, mutect2
- NGEF | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1328624341, COSV50918046; called by muse, mutect2
- NIBAN1 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 67/330 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62282440; called by muse, mutect2, varscan2
- NKX3-2 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as rs760235144, COSV66711798, COSV66712045; called by muse, mutect2, varscan2
- NLRP11 | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1413578343; called by muse, mutect2, varscan2
- NLRP3 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 150/377 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60230775; called by muse, mutect2, varscan2
- NOX5 | c.1521C>A p.H507Q | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52987053; called by muse, mutect2, varscan2
- NPAP1 | c.1934C>T p.P645L | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV61510428, COSV61511033; called by muse, mutect2, varscan2
- NPAP1 | c.2905G>T p.A969S | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV61506624; called by muse, mutect2, varscan2
- NPAS4 | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV60651563; called by muse, mutect2, varscan2
- NPR2 | c.1689G>T p.Q563H | Missense Mutation (SNP) | VAF 124/1037 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1461872898; called by muse, mutect2, varscan2
- NPTX2 | c.307C>A p.R103S | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99674822; called by muse, varscan2
- NRAP | c.3017C>T p.T1006I (on ENST00000359988 / NM_001322945.2; = p.T971I on NM_006175.4) | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1216613916, COSV100748187; called by muse, mutect2, varscan2
- NSG2 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as COSV57456943; called by mutect2, varscan2
- NTM | c.316G>T p.D106Y | Missense Mutation (SNP) | VAF 44/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100869371; called by muse, mutect2, varscan2
- NTRK3 | c.108T>G p.C36W | Missense Mutation (SNP) | VAF 140/455 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58111600; called by muse, mutect2, varscan2
- OLAH | c.622G>T p.V208F (on ENST00000378228 / NM_001039702.3; = p.V261F on NM_018324.3) | Missense Mutation (SNP) | VAF 68/242 reads (28%) | SIFT tolerated (0.71); PolyPhen benign (0.173); catalogued as rs754141411; called by muse, mutect2, varscan2
- OR10J3 | c.726C>A p.C242* | Nonsense Mutation (SNP) | VAF 44/283 reads (16%) | catalogued as COSV59955216, COSV59955893; called by muse, mutect2, varscan2
- OR10J5 | c.643A>G p.I215V | Missense Mutation (SNP) | VAF 67/320 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.107); catalogued as rs895397289; called by muse, mutect2, varscan2
- OR10Q1 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as COSV57472141; called by muse, mutect2, varscan2
- OR11L1 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63315593; called by muse, mutect2, varscan2
- OR14A16 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.506); catalogued as COSV100713687, COSV62926304, COSV62927619; called by muse, mutect2, varscan2
- OR2T33 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 52/493 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV58816357; called by muse, varscan2
- OR2T33 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 139/531 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV100532243; called by muse, mutect2, varscan2
- OR2T8 | c.256G>C p.G86R | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV100178478, COSV60662050; called by muse, mutect2, varscan2
- OR4C3 | c.184G>C p.A62P | Missense Mutation (SNP) | VAF 33/305 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV60583353; called by muse, mutect2
- OR51E2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756220257, COSV67807507; called by muse, mutect2, varscan2
- OR51Q1 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV56180058; called by muse, mutect2, varscan2
- OR52E2 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV58613733; called by muse, mutect2, varscan2
- OR52M1 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs891095972; called by muse, mutect2, varscan2
- OR52N1 | c.608T>C p.I203T | Missense Mutation (SNP) | VAF 52/495 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs375501780, COSV57693147; called by muse, mutect2, varscan2
- OR56A1 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV100360470; called by muse, mutect2, varscan2
- OR5T2 | c.705G>T p.Q235H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV57588178; called by muse, mutect2, varscan2
- OR5T2 | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as rs928821244; called by muse, varscan2
- OR6F1 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57469652; called by muse, mutect2, varscan2
- OR6V1 | c.457G>T p.A153S | Missense Mutation (SNP) | VAF 116/270 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV69236859; called by muse, mutect2, varscan2
- OR7A17 | c.439del p.A147Hfs*4 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | catalogued as COSV59414261; called by pindel, varscan2
- OR8K3 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.356); catalogued as COSV57132158; called by muse, mutect2, varscan2
- OR8K3 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.364); catalogued as rs1233134697; called by muse, mutect2, varscan2
- OTUD7A | c.1267G>C p.D423H (on ENST00000307050 / NM_001382637.1; = p.D416H on NM_130901.3) | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61039796; called by muse, mutect2, varscan2
- OVCH1 | c.2294G>T p.G765V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV58967893; called by muse, mutect2, varscan2
- OVGP1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 171/492 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100868177, COSV63858778; called by muse, mutect2, varscan2
- PABPN1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.029); catalogued as CM061882; called by muse, mutect2, varscan2
- PCDH15 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 51/356 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV57285651; called by muse, mutect2, varscan2
- PCDH19 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 102/152 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as CM091300, COSV55261037; called by muse, mutect2, varscan2
- PCDHA1 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 80/426 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV65375126; called by muse, mutect2, varscan2
- PCDHA11 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.052); catalogued as rs782065685; called by muse, mutect2, varscan2
- PCDHA2 | c.2128C>A p.L710M | Missense Mutation (SNP) | VAF 52/497 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV65371684; called by muse, mutect2, varscan2
- PCDHA3 | c.1840G>C p.G614R | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV63542996; called by muse, mutect2, varscan2
- PCDHA4 | c.2231C>A p.A744E | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.015); catalogued as COSV63541795; called by muse, mutect2, varscan2
- PCDHA7 | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV65343341; called by muse, mutect2, varscan2
- PCDHA7 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV65343347; called by muse, mutect2, varscan2
- PCDHB1 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 76/236 reads (32%) | catalogued as COSV60630016; called by muse, mutect2, varscan2
- PCDHB10 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 108/619 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); catalogued as rs1428124124; called by muse, mutect2, varscan2
- PCDHB14 | c.1052C>G p.S351W | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV53390285, COSV99032952; called by muse, varscan2
- PCDHB16 | c.322G>T p.V108L | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.049); catalogued as rs781999570; called by muse, varscan2
- PCDHB16 | c.353A>T p.Q118L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs1554282045; called by muse, varscan2
- PCDHB9 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 152/700 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV53375191, COSV53379472; called by muse, varscan2
- PCDHGA2 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 43/156 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV53950236; called by muse, mutect2, varscan2
- PCDHGA6 | c.2152C>A p.R718S | Missense Mutation (SNP) | VAF 42/395 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.283); catalogued as COSV54007806; called by muse, varscan2
- PCDHGA7 | c.1039G>T p.V347L | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.049); catalogued as rs764534858; called by muse, mutect2, varscan2
- PCDHGA9 | c.1262C>A p.T421K | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV54040754; called by muse, mutect2, varscan2
- PCDHGB6 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 102/266 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs946959934, COSV53996524; called by muse, mutect2, varscan2
- PCDHGB7 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 144/293 reads (49%) | catalogued as COSV53894124, COSV53920192; called by muse, mutect2, varscan2
- PCDHGC4 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.227); catalogued as rs139638334; called by muse, mutect2, varscan2
- PCLO | c.1154A>T p.Q385L | Missense Mutation (SNP) | VAF 130/265 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV61616906; called by muse, mutect2, varscan2
- PEG3 | c.2800A>T p.K934* | Nonsense Mutation (SNP) | VAF 18/150 reads (12%) | catalogued as COSV55651608; called by mutect2, varscan2
- PGR | c.1579G>T p.A527S | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs1253782670, COSV99677425; called by muse, mutect2, varscan2
- PIKFYVE | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 40/491 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as rs891262232, COSV100010811, COSV52238895; ClinVar: uncertain significance; called by muse, mutect2
- PKD1L1 | c.7796T>C p.M2599T | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1160137088; called by muse, mutect2, varscan2
- PKD1L1 | c.2047G>T p.G683W | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99221751; called by muse, mutect2, varscan2
- PKD1L1 | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 71/473 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs745425347, COSV99219013; called by muse, mutect2, varscan2
- PKD2L1 | c.1271C>A p.T424K | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV58396283; called by muse, mutect2, varscan2
- PKHD1L1 | c.4814G>A p.C1605Y | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV65750612; called by muse, mutect2, varscan2
- PLAG1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57611454; called by muse, mutect2, varscan2
- PLCB4 | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 79/367 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV53792321; called by muse, mutect2, varscan2
- PLEKHA6 | c.2937G>T p.Q979H | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55329861; called by muse, mutect2, varscan2
- PLEKHG7 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 132/289 reads (46%) | catalogued as COSV67337913; called by muse, mutect2, varscan2
- PLXNA4 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58119180; called by muse, mutect2, varscan2
- POLR2B | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs942724564; called by muse, varscan2
- POP4 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs750848621, COSV55676059; called by muse, mutect2, varscan2
- POTEB3 | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 48/601 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1250622194; called by muse, mutect2
- POTEC | c.293T>A p.M98K | Missense Mutation (SNP) | VAF 400/687 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.067); catalogued as COSV100743597; called by muse, varscan2
- POTEF | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 246/549 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV100665267, COSV62540756; called by muse, mutect2, varscan2
- POU1F1 | c.10C>A p.Q4K | Missense Mutation (SNP) | VAF 114/458 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs1320346151, CM034671; called by muse, mutect2, varscan2
- PPFIA2 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 72/235 reads (31%) | catalogued as COSV61059193; called by muse, mutect2, varscan2
- PPP1R32 | c.1108del p.Q370Rfs*36 | Frame Shift Del (DEL) | VAF 24/202 reads (12%) | catalogued as rs1565141981; called by mutect2, pindel, varscan2
- PRAMEF2 | c.419G>C p.R140T | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.136); catalogued as COSV53572968; called by muse, mutect2, varscan2
- PRICKLE2 | c.2584A>G p.S862G (on ENST00000295902; = p.S806G on NM_198859.4) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs1481689588; called by muse, mutect2, varscan2
- PROK2 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99816949; called by muse, mutect2, varscan2
- PRRC1 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99031353; called by muse, mutect2, varscan2
- PRSS41 | c.819G>T p.K273N | Missense Mutation (SNP) | VAF 90/222 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as rs765005238; called by muse, mutect2, varscan2
- PRSS48 | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 71/194 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs776335390; called by muse, mutect2, varscan2
- PRSS58 | c.577-1G>A p.X193_splice | Splice Site (SNP) | VAF 16/126 reads (13%) | catalogued as COSV101616153; called by muse, mutect2
- PRSS58 | c.457C>A p.Q153K | Missense Mutation (SNP) | VAF 88/206 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs1243017911, COSV73488504; called by muse, mutect2, varscan2
- PSG3 | c.119C>A p.A40D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59503466; called by muse, mutect2
- PSMA8 | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57603967; called by muse, varscan2
- PSMB11 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); catalogued as COSV101273398; called by muse, mutect2, varscan2
- PTCHD4 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 74/473 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100260444; called by muse, mutect2, varscan2
- PTF1A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 75/129 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100919567; called by muse, mutect2, varscan2
- PTK7 | c.1499-2A>G p.X500_splice | Splice Site (SNP) | VAF 37/143 reads (26%) | catalogued as COSV100030033; called by muse, mutect2, varscan2
- PTPRT | c.1814C>A p.T605K | Missense Mutation (SNP) | VAF 35/211 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV61968991, COSV62017284; called by muse, mutect2, varscan2
- RAPGEF4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.984); catalogued as rs773272442, COSV51378958; called by muse, mutect2, varscan2
- RCSD1 | c.84G>C p.R28S | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV63261035; called by muse, mutect2, varscan2
- RIC1 | c.2870A>G p.Q957R | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52609971; called by muse, mutect2, varscan2
- RIPK4 | c.1144G>A p.E382K (on ENST00000352483; = p.E334K on NM_020639.3) | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs935404461; called by muse, varscan2
- RNF152 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 365/754 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV57184429, COSV57186768; called by muse, mutect2, varscan2
- RNF31 | c.2062C>T p.R688W | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs985796955, COSV53758459; called by muse, mutect2, varscan2
- RPS6KA6 | c.1348A>G p.M450V | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1473156181; called by muse, mutect2, varscan2
- RSPO1 | c.722del p.R241Nfs*110 | Frame Shift Del (DEL) | VAF 31/262 reads (12%) | catalogued as COSV62974324; called by pindel, varscan2
- RUNX2 | c.500A>T p.E167V | Missense Mutation (SNP) | VAF 203/550 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV61845536; called by muse, mutect2, varscan2
- RUNX2 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 202/552 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV61842811; called by muse, mutect2, varscan2
- RYK | c.405G>A p.M135I | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1217002650; called by muse, mutect2, varscan2
- RYR2 | c.2125G>T p.G709W | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775143324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.13804C>T p.R4602* | Nonsense Mutation (SNP) | VAF 39/283 reads (14%) | catalogued as rs878853077, COSV63670601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S1PR5 | c.29del p.P10Rfs*2 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as COSV61013636; called by mutect2, pindel, varscan2
- SALL1 | c.3887G>T p.G1296V | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300014200; called by muse, mutect2, varscan2
- SALL4 | c.2621G>T p.R874L | Missense Mutation (SNP) | VAF 121/373 reads (32%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.522); catalogued as rs767816886; called by muse, mutect2, varscan2
- SAMD4A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 161/492 reads (33%) | catalogued as COSV51883758; called by muse, mutect2, varscan2
- SAMD9L | c.4568G>T p.R1523L | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59079879; called by muse, mutect2, varscan2
- SARS2 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV55501634; called by muse, mutect2
- SCN2A | c.5632C>A p.Q1878K | Missense Mutation (SNP) | VAF 181/406 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV51853394; called by muse, mutect2, varscan2
- SCN9A | c.2006G>A p.R669H (on ENST00000303354; = p.R658H on NM_002977.3) | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs200374987, COSV57616875; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEL1L2 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 111/336 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV99532840; called by muse, mutect2, varscan2
- SELENBP1 | c.665-2A>G p.X222_splice | Splice Site (SNP) | VAF 8/71 reads (11%) | catalogued as rs879125125; called by muse, mutect2, varscan2
- SEMA5A | c.1279G>C p.G427R | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66784394; called by muse, mutect2, varscan2
- SEMA5A | c.542C>A p.A181D | Missense Mutation (SNP) | VAF 265/521 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66800912; called by muse, mutect2, varscan2
- SEMA6D | c.2761A>G p.K921E (on ENST00000316364 / NM_153618.2; = p.K859E on NM_020858.2) | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs1315246138; called by muse, mutect2, varscan2
- SEMG1 | c.745G>T p.G249* | Nonsense Mutation (SNP) | VAF 74/296 reads (25%) | catalogued as COSV99725565; called by muse, mutect2
- SERPINA9 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs758602903; called by muse, mutect2, varscan2
- SH2D4A | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 25/210 reads (12%) | catalogued as rs747555610, COSV56121856; called by muse, mutect2, varscan2
- SH3GL2 | c.494G>T p.R165L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101014627; called by muse, mutect2, varscan2
- SHANK3 | c.2176G>T p.A726S | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.867); catalogued as rs376095125; called by muse, mutect2, varscan2
- SI | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 68/439 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1181769104; called by muse, mutect2, varscan2
- SIRT5 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 50/197 reads (25%) | catalogued as rs747218492; called by muse, mutect2, varscan2
- SKOR2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as rs1259789700; called by muse, mutect2, varscan2
- SLAMF7 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 54/228 reads (24%) | catalogued as COSV100833205; called by muse, varscan2
- SLC38A5 | c.1036G>C p.V346L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV58333563; called by muse, mutect2, varscan2
- SLC5A1 | c.711G>T p.M237I | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV56687815; called by muse, mutect2, varscan2
- SLC5A10 | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 135/260 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58760682; called by muse, mutect2, varscan2
- SLC5A10 | c.1486C>A p.P496T (on ENST00000395645 / NM_001042450.4; = p.P512T on NM_152351.5) | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV52413026; called by muse, mutect2, varscan2
- SLC6A7 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as rs192386891; called by mutect2, varscan2
- SLC7A10 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 20/133 reads (15%) | catalogued as rs1340482187; called by muse, mutect2, varscan2
- SLC7A11 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54929030; called by muse, mutect2, varscan2
- SLITRK3 | c.2753C>A p.P918H | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs761721011; called by muse, mutect2, varscan2
- SMO | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.118); catalogued as COSV50824193; called by muse, mutect2, varscan2
- SNAI1 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1287163992; called by muse, mutect2, varscan2
- SON | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 37/334 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.057); catalogued as rs192269145; called by muse, mutect2, varscan2
- SORCS1 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs755039220; called by muse, mutect2, varscan2
- SPATA22 | c.594G>C p.Q198H | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.995); catalogued as COSV52152496; called by muse, mutect2
- SPECC1 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs374644443; called by muse, mutect2, varscan2
- SPEM2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 169/283 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1416147063; called by muse, mutect2, varscan2
- SPTA1 | c.900A>T p.E300D | Missense Mutation (SNP) | VAF 60/422 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1174094355; called by muse, mutect2, varscan2
- SPTBN2 | c.5611G>T p.A1871S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59454886; called by muse, mutect2, varscan2
- SPTBN4 | c.6581G>T p.R2194L | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.931); catalogued as rs1001546965; called by muse, mutect2, varscan2
- SRCAP | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.484); catalogued as COSV52676565; called by muse, mutect2, varscan2
- SRP54 | c.1078A>G p.M360V | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1326323536; called by muse, mutect2, varscan2
- SRRT | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as rs1359056291; called by muse, mutect2, varscan2
- SSPOP | n.5916+1del | Splice Region (DEL) | VAF 18/48 reads (38%) | catalogued as COSV100022296; called by mutect2, pindel, varscan2
- ST8SIA2 | c.1044G>T p.M348I | Missense Mutation (SNP) | VAF 47/178 reads (26%) | PolyPhen probably damaging (0.996); catalogued as rs1454259909; called by muse, mutect2, varscan2
- STAC2 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 26/360 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368038617; called by muse, mutect2
- STC2 | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.206); catalogued as COSV99438395; called by muse, mutect2, varscan2
- STYXL2 | c.298G>T p.V100F | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs547250427; called by muse, mutect2, varscan2
- SYNE1 | c.20645C>T p.S6882L (on ENST00000367255 / NM_182961.4; = p.S6811L on NM_033071.3) | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs373012438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.16411G>T p.G5471C (on ENST00000367255 / NM_182961.4; = p.G5400C on NM_033071.3) | Missense Mutation (SNP) | VAF 74/369 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99585872; called by muse, mutect2, varscan2
- TARM1 | c.487C>A p.P163T (on ENST00000616041 / NM_001330650.1; = p.P155T on NM_001135686.3) | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.844); catalogued as rs755232522; called by muse, mutect2, varscan2
- TBC1D10C | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.608); catalogued as rs767406445, COSV56702250; called by muse, mutect2, varscan2
- TC2N | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 185/629 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs759603073; called by muse, mutect2, varscan2
- TCAP | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 36/73 reads (49%) | catalogued as CM152997; called by muse, mutect2, varscan2
- TDRD12 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs1430202718; called by muse, mutect2, varscan2
- TDRD6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.946); catalogued as COSV60175170; called by muse, mutect2, varscan2
- TDRD7 | c.2252G>A p.R751K | Missense Mutation (SNP) | VAF 46/428 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs1383644440; called by muse, mutect2
- TEX33 | c.746G>T p.G249V (on ENST00000381821 / NM_001163857.2; = p.G164V on NM_178552.4) | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV67822208; called by muse, mutect2, varscan2
- TGM6 | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 189/654 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs757930415; called by muse, mutect2, varscan2
- THBS2 | c.2249C>A p.T750N | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as rs1340855303, COSV100827982; called by muse, mutect2, varscan2
- THEMIS | c.806C>G p.S269* | Nonsense Mutation (SNP) | VAF 27/98 reads (28%) | catalogued as COSV64073552; called by muse, mutect2, varscan2
- THSD7A | c.3559C>T p.R1187W | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs986010893, COSV69855313; called by muse, mutect2, varscan2
- TIAM1 | c.1758G>T p.M586I | Missense Mutation (SNP) | VAF 100/242 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV54552876; called by muse, mutect2, varscan2
- TLN2 | c.3536G>T p.G1179V | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.356); catalogued as rs527611972; called by muse, mutect2, varscan2
- TLN2 | c.7177G>T p.G2393W | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60891006; called by muse, mutect2, varscan2
- TMEM151A | c.858G>T p.W286C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.79); catalogued as rs899189437; called by muse, mutect2
- TMEM159 | c.29C>G p.S10* | Nonsense Mutation (SNP) | VAF 79/236 reads (33%) | catalogued as COSV51786209, COSV99238871; called by muse, mutect2, varscan2
- TMEM40 | c.300C>A p.P100= | Splice Region (SNP) | VAF 15/60 reads (25%) | catalogued as rs1240228265, COSV53147889; called by muse, mutect2, varscan2
- TMPRSS7 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 93/403 reads (23%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1334443766; called by muse, mutect2, varscan2
- TMTC4 | c.1658G>A p.W553* (on ENST00000376234 / NM_001350577.2; = p.W572* on NM_032813.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as rs1268476872; called by muse, mutect2, varscan2
- TNN | c.2149G>C p.D717H | Missense Mutation (SNP) | VAF 171/648 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV53421878, COSV53423613; called by muse, mutect2, varscan2
- TNR | c.2600del p.P867Qfs*9 | Frame Shift Del (DEL) | VAF 23/134 reads (17%) | catalogued as rs1557886412; called by pindel, varscan2
- TNXB | c.10408G>T p.G3470C (on ENST00000647633; = p.G3223C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1307234916; called by muse, mutect2, varscan2
- TOR1AIP1 | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.735); catalogued as rs777161352; called by muse, mutect2, varscan2
- TRANK1 | c.6472G>A p.E2158K | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.259); catalogued as rs756145719, COSV57167156; called by muse, mutect2, varscan2
- TRAV21 | c.54C>A p.S18R | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs1348163055; called by muse, mutect2
- TRBV2 | c.84C>G p.S28R | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs775052218; called by muse, mutect2, varscan2
- TRIM49 | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 69/504 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61670760; called by muse, mutect2, varscan2
- TRIM58 | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100824873, COSV63572253; called by muse, mutect2, varscan2
- TRIP12 | c.2567A>T p.H856L | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV52275308; called by muse, mutect2, varscan2
- TRPC3 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs1333970724, COSV101108689; called by muse, mutect2, varscan2
- TRPM2 | c.2359C>A p.R787S | Missense Mutation (SNP) | VAF 75/187 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55968471; called by muse, mutect2, varscan2
- TRPV5 | c.1971G>T p.E657D | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.149); catalogued as COSV54690602; called by muse, mutect2, varscan2
- TRPV5 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 69/476 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs779621537, COSV54685314; called by muse, mutect2, varscan2
- TSHZ3 | c.752C>G p.P251R | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.402); catalogued as COSV53666372; called by muse, mutect2, varscan2
- TSPAN19 | c.388G>T p.G130* | Nonsense Mutation (SNP) | VAF 54/177 reads (31%) | catalogued as COSV101468091; called by muse, mutect2, varscan2
- TTC28 | c.2633G>T p.R878L | Missense Mutation (SNP) | VAF 40/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67424704; called by muse, varscan2
- TTK | c.2062A>G p.N688D | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57886058; called by muse, mutect2, varscan2
- TTLL6 | c.2600G>T p.R867M (on ENST00000393382 / NM_001130918.3; = p.R560M on NM_173623.3) | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV64979702; called by muse, mutect2
- TUBB4A | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 171/317 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV51156026; called by muse, mutect2, varscan2
- TWNK | c.1123G>T p.E375* | Nonsense Mutation (SNP) | VAF 39/280 reads (14%) | catalogued as COSV52967273; called by muse, mutect2, varscan2
- TXNL4B | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.065); catalogued as rs921174693; called by muse, mutect2, varscan2
- UBAP2 | c.602A>T p.D201V | Missense Mutation (SNP) | VAF 20/496 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV62546336; called by muse, mutect2
- UGDH | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 69/455 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1182319939; called by muse, mutect2, varscan2
- UIMC1 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV101022167; called by muse, mutect2
- UNC13C | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 127/450 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs778488641, COSV99520056; called by muse, mutect2, varscan2
- UNC5C | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 77/328 reads (23%) | catalogued as COSV71660250; called by muse, mutect2, varscan2
- UNC79 | c.3953A>G p.Y1318C (on ENST00000393151 / NM_001346218.2; = p.Y1141C on NM_020818.5) | Missense Mutation (SNP) | VAF 56/314 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs754475637, COSV56400128; called by muse, varscan2
- UNCX | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 95/206 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs751585310, COSV60332782; called by muse, mutect2, varscan2
- VIP | c.181T>A p.L61M | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV65888906; called by muse, mutect2, varscan2
- VRTN | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56440734; called by muse, mutect2, varscan2
- VSIG4 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs751653148; called by muse, varscan2
- VSX2 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 163/375 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1157581343; called by muse, mutect2, varscan2
- VWDE | c.2282T>C p.L761S | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs1226691145; called by muse, mutect2, varscan2
- WDR18 | c.395A>G p.D132G | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs762562537; called by muse, mutect2, varscan2
- WDR61 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 108/389 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.948); catalogued as rs1464400282, COSV51217496; called by muse, mutect2, varscan2
- WDR87 | c.7016G>A p.R2339K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58193241; called by muse, mutect2, varscan2
- WDR87 | c.4655G>T p.R1552L | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV58193274; called by muse, mutect2, varscan2
- WNK4 | c.1522C>A p.R508S | Missense Mutation (SNP) | VAF 210/443 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV99889410; called by muse, mutect2, varscan2
- XIRP1 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as rs1023169527; called by muse, mutect2, varscan2
- XIRP2 | c.5422C>A p.P1808T (on ENST00000628543; = p.P1983T on NM_152381.6) | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.091); catalogued as rs779187045; called by muse, mutect2, varscan2
- ZCCHC8 | c.1140+1G>A p.X380_splice | Splice Site (SNP) | VAF 66/165 reads (40%) | catalogued as rs1043766849, COSV60317238; called by muse, mutect2, varscan2
- ZFP82 | c.1000G>T p.G334C | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101088873, COSV101089213; called by muse, varscan2
- ZIC3 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.387); catalogued as CM140977; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2661C>A p.Y887* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | catalogued as COSV60156495; called by muse, mutect2
- ZNF254 | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs1191252984; called by muse, mutect2, varscan2
- ZNF398 | c.175A>T p.I59F | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV60065285; called by muse, mutect2, varscan2
- ZNF446 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs151034980, COSV99543101; called by muse, mutect2
- ZNF532 | c.2716A>G p.K906E | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV60171889; called by muse, mutect2, varscan2
- ZNF536 | c.3106G>T p.G1036W | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62835658; called by muse, varscan2
- ZNF560 | c.1334C>A p.P445Q | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV56870991; called by muse, mutect2, varscan2
- ZNF574 | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | PolyPhen benign (0); catalogued as rs896826973; called by muse, mutect2, varscan2
- ZNF577 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV56814648; called by muse, mutect2, varscan2
- ZNF676 | c.1028G>T p.C343F (on ENST00000650058; = p.C311F on NM_001001411.3) | Missense Mutation (SNP) | VAF 42/354 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68092245; called by muse, mutect2, varscan2
- ZNF717 | c.1421C>T p.T474I | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as rs79406015, COSV68859073; called by muse, mutect2, varscan2
- ZNF835 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as rs1389692442; called by muse, mutect2, varscan2
- ZNF853 | c.1258G>A p.G420R | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs997814479; called by muse, mutect2, varscan2
- ZNF865 | c.1946C>G p.P649R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101642859; called by mutect2, varscan2
- ZNFX1 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV65577544; called by muse, mutect2, varscan2
- ZPBP | c.751C>A p.H251N | Missense Mutation (SNP) | VAF 65/761 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV50425857; called by muse, mutect2
- ZPBP | c.487+1G>T p.X163_splice | Splice Site (SNP) | VAF 16/161 reads (10%) | catalogued as COSV50434906; called by muse, mutect2, varscan2
- ZSCAN18 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.75); catalogued as rs1241535257; called by muse, mutect2
- ZSWIM2 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54574226; called by muse, mutect2, varscan2
- A2M | c.1207G>T p.G403C | Missense Mutation (SNP) | VAF 88/530 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA10 | c.2776A>T p.I926L | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA12 | c.4422G>T p.K1474N (on ENST00000272895 / NM_173076.3; = p.K1156N on NM_015657.3) | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ABCA12 | c.1700A>T p.E567V (on ENST00000272895 / NM_173076.3; = p.E249V on NM_015657.3) | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCA13 | c.13383C>A p.C4461* | Nonsense Mutation (SNP) | VAF 77/168 reads (46%) | called by muse, mutect2, varscan2
- ABCC2 | c.1276G>A p.V426M | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ABCG5 | c.317C>A p.A106E | Missense Mutation (SNP) | VAF 81/139 reads (58%) | SIFT tolerated (0.67); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ABHD4 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ACAD9 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAN | c.6625C>A p.L2209M | Missense Mutation (SNP) | VAF 84/299 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ACCSL | c.192C>G p.I64M | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ACE | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.035); called by muse, mutect2
- ACE2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ACOT11 | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ACP7 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- ACSF3 | c.-21G>T | Splice Region (SNP) | VAF 67/166 reads (40%) | called by muse, mutect2, varscan2
- ACSM1 | c.1593G>C p.K531N | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ACSM1 | c.1299+2T>C p.X433_splice | Splice Site (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2
- ACSM3 | c.819G>C p.W273C | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTC1 | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 35/284 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- ACTN2 | c.76dup p.W26Lfs*24 | Frame Shift Ins (INS) | VAF 47/139 reads (34%) | called by mutect2, pindel, varscan2
- ACTR10 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 120/368 reads (33%) | called by muse, mutect2, varscan2
- ACVR1C | c.704A>T p.E235V | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR2B | c.979G>C p.V327L | Missense Mutation (SNP) | VAF 55/441 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, varscan2
- ADAM8 | c.2378C>T p.A793V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ADAMTS10 | c.1798-1G>T p.X600_splice | Splice Site (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.2641C>G p.P881A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS16 | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS2 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ADAMTS20 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ADAMTS3 | c.429G>T p.Q143H | Missense Mutation (SNP) | VAF 51/259 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS4 | c.1871A>T p.Q624L | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ADAMTSL3 | c.1139G>T p.C380F | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAMTSL5 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAT3 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 95/141 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ADCY1 | c.1495A>C p.M499L | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY10 | c.1379A>G p.Y460C | Missense Mutation (SNP) | VAF 123/596 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY7 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 118/219 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.265+2T>A p.X89_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
- ADGB | c.4293C>A p.S1431R | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ADGRA1 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ADGRB3 | c.3405T>G p.F1135L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADGRF5 | c.3075G>T p.L1025F | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- ADGRV1 | c.9714G>T p.Q3238H | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ADRA1A | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 152/277 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AFF3 | c.1233G>T p.K411N | Missense Mutation (SNP) | VAF 70/124 reads (56%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.691); called by muse, varscan2
- AGA | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- AGAP9 | c.1471A>T p.S491C | Missense Mutation (SNP) | VAF 65/636 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGO2 | c.1615G>T p.V539L | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGTR1 | c.833A>T p.D278V | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- AHNAK | c.13890G>T p.R4630S | Missense Mutation (SNP) | VAF 98/329 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, varscan2
- AHNAK | c.13889G>T p.R4630M | Missense Mutation (SNP) | VAF 95/328 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, varscan2
- AHNAK2 | c.16052C>A p.P5351H | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- AK7 | c.1429G>C p.G477R | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AKAP3 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 78/183 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP4 | c.2080G>T p.G694W | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP9 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 45/418 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- AKR7A3 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- AL121899.2 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 82/325 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- AL121899.2 | c.1806G>T p.E602D | Missense Mutation (SNP) | VAF 101/372 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALG10 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 139/462 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.296); called by muse, varscan2
- ALPK1 | c.2768A>G p.N923S | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPK1 | c.2829G>T p.E943D | Missense Mutation (SNP) | VAF 54/237 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALPK2 | c.4855A>T p.T1619S | Missense Mutation (SNP) | VAF 83/480 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ALX4 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 116/286 reads (41%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.025); called by muse, varscan2
- AMACR | c.950C>T p.T317I | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- ANAPC4 | c.2108G>T p.R703L | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ANK2 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 206/636 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by mutect2, varscan2
- ANK2 | c.8357C>A p.A2786D | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ANK3 | c.7028C>T p.T2343I | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD17 | c.7187G>T p.G2396V | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.567); called by muse, mutect2, varscan2
- ANKRD31 | c.3984G>T p.V1328= | Splice Region (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- ANKS1A | c.2318del p.P773Lfs*30 | Frame Shift Del (DEL) | VAF 56/162 reads (35%) | called by mutect2, pindel, varscan2
- AP3B2 | c.1722T>A p.D574E | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AP4E1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.4224A>T p.E1408D | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2
- APOBEC3A | c.174+1G>T p.X58_splice | Splice Site (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2
- AR | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 115/211 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ARAP1 | c.2477G>T p.R826L (on ENST00000393609 / NM_001040118.2; = p.R581L on NM_015242.4) | Missense Mutation (SNP) | VAF 48/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP11A | c.859G>T p.G287* | Nonsense Mutation (SNP) | VAF 24/196 reads (12%) | called by muse, mutect2
- ARHGAP6 | c.577T>A p.W193R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ARHGEF10L | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 117/370 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGEF26 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ARHGEF28 | c.3445G>A p.E1149K | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGEF7 | c.412G>T p.G138W (on ENST00000375741 / NM_001113511.2; = p.G117W on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ARID1A | c.2603A>T p.Y868F | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARID4A | c.2544A>T p.Q848H | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- ARIH1 | c.583A>T p.N195Y | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARIH1 | c.896G>T p.C299F | Missense Mutation (SNP) | VAF 50/281 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARNT | c.2187G>T p.W729C | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARNT | c.2185T>G p.W729G | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- ASB2 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ASB5 | c.869del p.P290Qfs*16 | Frame Shift Del (DEL) | VAF 25/160 reads (16%) | called by mutect2, pindel, varscan2
- ASTN1 | c.2416C>A p.L806M | Missense Mutation (SNP) | VAF 59/332 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); called by muse, varscan2
- ASXL3 | c.3697A>T p.K1233* | Nonsense Mutation (SNP) | VAF 91/258 reads (35%) | called by muse, mutect2, varscan2
- ATP13A2 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ATP2B1 | c.2011G>T p.V671F | Missense Mutation (SNP) | VAF 119/286 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ATP2B4 | c.650-1G>T p.X217_splice | Splice Site (SNP) | VAF 15/79 reads (19%) | called by muse, mutect2, varscan2
- ATP7B | c.3124del p.V1042Cfs*79 | Frame Shift Del (DEL) | VAF 70/193 reads (36%) | called by mutect2, pindel, varscan2
- ATPAF1 | c.160G>C p.G54R (on ENST00000574428; = p.G77R on NM_022745.4) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN2 | c.3457C>G p.P1153A (on ENST00000550104; = p.P993A on NM_002973.4) | Missense Mutation (SNP) | VAF 108/254 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- AUTS2 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- B3GALT2 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- B4GALNT4 | c.1308C>G p.D436E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- B4GALT4 | c.540A>T p.E180D | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BARX1 | c.359A>C p.E120A | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- BAZ1B | c.1463G>T p.R488M | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- BBOX1 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCAN | c.1606C>A p.H536N | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BCAS3 | c.2617G>T p.D873Y (on ENST00000390652 / NM_001353144.2; = p.D858Y on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- BCL9L | c.2929C>T p.Q977* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | called by muse, mutect2
- BECN1 | c.489-2A>G p.X163_splice | Splice Site (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- BEX1 | c.110C>A p.P37H | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- BFSP2 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BICC1 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 52/298 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- BLK | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 141/608 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMP3 | c.553G>C p.V185L | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BNC2 | c.415_417delinsAA p.H139Kfs*36 | Frame Shift Del (DEL) | VAF 36/266 reads (14%) | called by pindel, varscan2*
- BOD1L2 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.887); called by muse, varscan2
- BOD1L2 | c.41dup p.A15Gfs*39 | Frame Shift Ins (INS) | VAF 26/70 reads (37%) | called by pindel, varscan2
- BOD1L2 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- BPIFB2 | c.1128G>T p.Q376H | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- BPIFB4 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 105/315 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- BRCA2 | c.1291A>G p.T431A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BRDT | c.1988G>T p.S663I | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- BRF1 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.6262G>A p.A2088T | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- BSN | c.6271A>T p.S2091C | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- BTBD3 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 117/385 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- BTBD8 | c.3834dup p.G1279Wfs*4 (on ENST00000636805 / NM_001376131.1; = p.G766Wfs*4 on NM_015237.4) | Frame Shift Ins (INS) | VAF 30/138 reads (22%) | called by mutect2, pindel, varscan2
- BUB1B | c.1639G>T p.D547Y | Missense Mutation (SNP) | VAF 146/611 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- C10orf71 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.678); called by muse, mutect2
- C10orf99 | c.206C>A p.P69H | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C12orf50 | c.552T>A p.H184Q | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- C12orf50 | c.481+1G>T p.X161_splice | Splice Site (SNP) | VAF 67/175 reads (38%) | called by muse, mutect2, varscan2
- C12orf60 | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C17orf107 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- C1orf167 | c.1045C>A p.L349M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2
- C2CD2L | c.569A>T p.Q190L | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- C3orf20 | c.1593C>G p.D531E | Missense Mutation (SNP) | VAF 61/209 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- C4orf33 | c.70A>T p.N24Y | Missense Mutation (SNP) | VAF 99/445 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, varscan2
- C4orf54 | c.3589G>T p.A1197S | Missense Mutation (SNP) | VAF 57/175 reads (33%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- C9orf131 | c.3019C>G p.L1007V | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CA10 | c.350T>A p.I117K | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CA4 | c.237A>C p.Q79H | Missense Mutation (SNP) | VAF 96/653 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CABIN1 | c.884del p.G295Afs*22 | Frame Shift Del (DEL) | VAF 52/303 reads (17%) | called by mutect2, pindel, varscan2
- CACNA1A | c.3824C>A p.P1275H | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); called by muse, varscan2
- CACNA1A | c.2860G>T p.G954C | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CACNA1E | c.5408T>C p.V1803A | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, varscan2
- CACNG2 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CALM3 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CALU | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAMK2B | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 37/258 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMTA1 | c.1079T>A p.V360E | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CANX | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- CARD11 | c.3278C>A p.P1093H | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- CARNMT1 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CCAR1 | c.601A>G p.N201D | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC141 | c.1899+5G>T | Splice Region (SNP) | VAF 66/232 reads (28%) | called by muse, mutect2, varscan2
- CCDC158 | c.3050A>C p.K1017T | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC168 | c.8378C>A p.A2793E | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- CCDC169 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC180 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CCDC27 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CCDC30 | c.689A>G p.Q230R (on ENST00000340612; = p.Q187R on NM_001080850.3) | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CCDC33 | c.1804T>A p.L602M | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CCDC73 | c.2102C>A p.P701H | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- CCDC80 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CCDC87 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC88B | c.3289G>T p.V1097L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- CCKBR | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CCL26 | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
- CCL3 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 198/508 reads (39%) | called by muse, mutect2, varscan2
- CCND2 | c.780G>T p.Q260H | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CCR3 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 67/296 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CCRL2 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCZ1B | c.439-4C>T | Splice Region (SNP) | VAF 57/333 reads (17%) | called by muse, mutect2, varscan2
- CD14 | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CD163L1 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 94/282 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CD1C | c.976C>A p.H326N | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CD248 | c.1018G>T p.G340* | Nonsense Mutation (SNP) | VAF 94/284 reads (33%) | called by muse, mutect2, varscan2
- CD36 | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 31/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CD46 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 101/460 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- CD6 | c.1969A>T p.T657S | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDC14C | c.377A>T p.Y126F (on ENST00000428251; = p.Y19F on NM_152627.3) | Missense Mutation (SNP) | VAF 99/230 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH19 | c.535T>A p.S179T | Missense Mutation (SNP) | VAF 186/461 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDH23 | c.1716G>T p.E572D | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CDHR1 | c.152-2A>T p.X51_splice | Splice Site (SNP) | VAF 58/372 reads (16%) | called by muse, mutect2, varscan2
- CDHR1 | c.1921C>A p.L641M | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CDYL | c.1506G>T p.M502I (on ENST00000328908 / NM_001368125.1; = p.M448I on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/151 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- CEACAM8 | c.1042C>A p.L348M | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- CEL | c.1430G>T p.R477L (on ENST00000673714; = p.R474L on NM_001807.6) | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.228); called by muse, varscan2
- CELF4 | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP161 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CFAP20DC | c.1309A>T p.S437C (on ENST00000482387 / NM_001351530.2; = p.S312C on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CFAP47 | c.7022A>T p.Q2341L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.025); called by muse, mutect2
- CFAP53 | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 142/369 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CFAP58 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, varscan2
- CFAP92 | c.602A>T p.K201I | Missense Mutation (SNP) | VAF 96/406 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- CFH | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 58/222 reads (26%) | called by muse, mutect2, varscan2
- CHD9 | c.6175T>A p.S2059T | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CHST1 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST2 | c.1366C>A p.L456M | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHST8 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CILK1 | c.763A>T p.S255C | Missense Mutation (SNP) | VAF 91/448 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CLCNKA | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2
- CLEC12A | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 86/422 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- CLN6 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 30/268 reads (11%) | called by muse, mutect2, varscan2
- CNGA2 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CNGB3 | c.2261C>A p.P754H | Missense Mutation (SNP) | VAF 189/369 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CNPY2 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 153/265 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTFR | c.1006G>T p.D336Y | Missense Mutation (SNP) | VAF 40/607 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
1,704 further variants in this file (906 protein-altering or splice-affecting, 486 silent, 312 other) are not listed here.
